Somatic mutation profile of tumor specimen TCGA-06-0139-01A (aliquot TCGA-06-0139-01A-01D-1490-08) from TCGA case TCGA-06-0139, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 40.3 years (14,729 days).
Specimen TCGA-06-0139-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f8fa2dc-a7d1-41fa-9588-95d4b41c00dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0139-10A (Blood Derived Normal), aliquot TCGA-06-0139-10A-01D-1490-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10b81151-18ef-4fb8-bc25-712e8b2943ad

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EXOC7 | c.513G>T p.L171F | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV58744010; called by muse, mutect2
- OR4F6 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV61027349; called by muse, mutect2
- AL109984.1 | n.186+1698G>A | Intron (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
